Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACH, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACH-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: Left lobe HCC

Specimen : Liver

Gross Photo :

GROSS:

1. Specimen: Liver: 13.5 x 9.5 x 7.5 cm and 371.5 gm
2. Tumor location: left
Tumor number: one
Tumor size: 9.0 x 7.5 x 7.0 cm
(Received liver is nearly almost involved by tumor)
3. Satellite nodule: no
4. Gross type
HCC: infiltrative
5. Tumor necrosis: yes (5 %),
6. Capsular formation is absent
7. Portal vein invasion:
yes (grossly, left portal vein thrombosis is identified)
8. Bile duct invasion: no
9. Other organ:
Gallbladder:
10.0 cm in length, 4.5 cm in diameter, 0.4 cm in wall thickness
10. Tissue labelled as 'left portal vein resection margin'(Entirely submitted):
No tumor present

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
QJ 5/19/14

Gross photo present.

Blocks

T1-5, tumor x 5
A, tissue labelled as 'left portal vein resection margin' x 1
GB, gallbladder x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes
- 1-1. Differentiation
The worst differentiation III
The major differentiation III
- 1-2. Histologic type: trabecular
- 1-3. Cell type: hepatic
- 1-4. Fatty change: no

[page 2 of 3]
2. Cholangiocarcinoma: no
3. Fibrous capsule formation: no
4. Septum formation: no
5. Surgical resection margin invasion: margin of the clearance (0.5 cm)
6. Serosal invasion: no
7. Portal vein invasion: yes
8. Bile duct invasion: no
9. Hepatic vein invasion: no
10. Hepatic artery invasion: no
11. Microvessel invasion: yes
12. Intrahepatic metastasis: no
13. Multicentric occurrence: no

Nom-tumor liver pathology

1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: micronodular
2. Dysplastic nodule: no
3. Ductal epithelial dysplasia: no
4. Other liver diseases: no

SPECIAL STAIN: Trichrome stains reveals fibrotic nodule of the liver.

NOT reported. Gross:

NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma,cirrhosis
T56000, P10, M81703, M49500
gallbladder,ectomy,chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, left, lobectomy:

Hepatocellular carcinoma, moderately differentiated

Cirrhosis, micronodular

Gallbladder, cholecystectomy:

Chronic cholecystitis

Blood vessel, labelled as 'left portal vein', frozen biopsy:

[page 3 of 3]
No tumor present

Suggestion :

Source: NCI Genomic Data Commons file 4ad484cd-24f4-45ff-8694-ac3b7cc8c470 (TCGA-DD-AACH.573AD8A4-3D0A-4128-BAD8-2FDC5B480DE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).